Somatic mutation profile of tumor specimen TARGET-10-PARBKP-09A (aliquot TARGET-10-PARBKP-09A-01D) from TARGET case TARGET-10-PARBKP, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.8 years (2,115 days).
Specimen TARGET-10-PARBKP-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 96f36e02-458a-4e19-b5b1-ac8e622c7607.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARBKP-10A (Blood Derived Normal), aliquot TARGET-10-PARBKP-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/49653aea-7d74-4339-8ca8-b3e187db89da

The open-access MAF lists 77 somatic variants for this specimen: 44 protein-altering or splice-affecting, 14 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 14, Intron 14, Nonsense Mutation 3, 5'UTR 2, 3'Flank 1, 3'UTR 1, Frame Shift Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 8/52 reads (15%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 10/56 reads (18%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, varscan2
- ABCD2 | c.628C>G p.L210V | Missense Mutation (SNP) | VAF 46/97 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV58054452; called by muse, mutect2, varscan2
- ARHGEF12 | c.524C>G p.S175C | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.682); catalogued as COSV63103006; called by muse, mutect2, varscan2
- CLCA4 | c.1387G>C p.E463Q | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.93); PolyPhen benign (0.021); catalogued as COSV55368103; called by muse, mutect2, varscan2
- CNTN5 | c.2240G>A p.R747Q | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1175757582; called by muse, mutect2, varscan2
- DOCK5 | c.1240C>T p.Q414* | Nonsense Mutation (SNP) | VAF 15/52 reads (29%) | catalogued as COSV52403085; called by muse, mutect2, varscan2
- GPR176 | c.961C>T p.L321F | Missense Mutation (SNP) | VAF 31/56 reads (55%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as rs773339133, COSV100137011; called by muse, mutect2, varscan2
- MAPK11 | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.54); PolyPhen benign (0.029); catalogued as rs202139039, COSV100404521, COSV100404561; called by muse, mutect2, varscan2
- OR5M11 | c.230C>A p.A77E | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as COSV73141680; called by muse, mutect2, varscan2
- PAX1 | c.863C>T p.S288L | Missense Mutation (SNP) | VAF 40/75 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs767792155, COSV68273467; called by muse, mutect2, varscan2
- PGK2 | c.319G>T p.A107S | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.071); catalogued as rs769088283, COSV59163400; called by muse, varscan2
- TEX49 | c.94G>C p.E32Q | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.59); PolyPhen benign (0.04); catalogued as rs1166724299; called by muse, mutect2, varscan2
- ZNF134 | c.366C>G p.S122R | Missense Mutation (SNP) | VAF 5/98 reads (5%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs1247367198; called by muse, mutect2
- C2orf16 | c.841C>G p.P281A | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.307); called by muse, mutect2, varscan2
- CCDC51 | c.46G>A p.V16M | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- CHD7 | c.4326G>C p.M1442I | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- CNGB1 | c.901G>C p.E301Q | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CNST | c.939G>C p.E313D | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.43); PolyPhen benign (0.325); called by muse, mutect2, varscan2
- COL11A2 | c.1723G>A p.D575N (on ENST00000341947 / NM_080680.3; = p.D468N on NM_080679.2) | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- DPP4 | c.1135G>A p.E379K | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.25); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FLI1 | c.946G>A p.E316K | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- FSTL5 | c.1378G>A p.D460N | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- GAREM1 | c.903G>C p.L301F | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- GLI3 | c.161G>T p.R54I | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- HCK | c.14C>G p.S5* | Nonsense Mutation (SNP) | VAF 11/26 reads (42%) | called by muse, mutect2, varscan2
- IL1RL1 | c.454C>G p.Q152E | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KDF1 | c.1136C>G p.S379* | Nonsense Mutation (SNP) | VAF 11/29 reads (38%) | called by muse, mutect2, varscan2
- KRT40 | c.468G>C p.E156D | Missense Mutation (SNP) | VAF 59/111 reads (53%) | SIFT tolerated (0.2); PolyPhen benign (0.364); called by muse, mutect2
- MAP2 | c.2672G>A p.G891E | Missense Mutation (SNP) | VAF 36/71 reads (51%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- MCIDAS | c.647C>T p.S216L | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- MED12 | c.1827C>G p.F609L | Missense Mutation (SNP) | VAF 28/38 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- NADSYN1 | c.1508C>G p.S503C | Missense Mutation (SNP) | VAF 35/57 reads (61%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- NCOR1 | c.3052C>T p.L1018F | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- POSTN | c.1041del p.N347Kfs*6 | Frame Shift Del (DEL) | VAF 10/71 reads (14%) | called by mutect2, pindel, varscan2
- SCN3A | c.5881A>G p.S1961G | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.431); called by muse, mutect2, varscan2
- SP6 | c.149G>A p.G50E | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- STAM2 | c.1066G>A p.E356K | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- SZT2 | c.5422G>A p.A1808T (on ENST00000634258 / NM_001365999.1; = p.A1751T on NM_015284.4) | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2
- TARS3 | c.1765G>C p.E589Q | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- TBC1D9B | c.2932G>A p.E978K (on ENST00000356834 / NM_198868.3; = p.E961K on NM_015043.4) | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- TGM5 | c.1130C>G p.S377C (on ENST00000220420 / NM_201631.4; = p.S295C on NM_004245.4) | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TPP1 | c.409G>C p.E137Q | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.4); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ZNF16 | c.952G>A p.E318K | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- ADAM18 | c.21C>G p.L7= | Silent (SNP) | VAF 15/40 reads (38%) | called by muse, mutect2, varscan2
- ALK | c.648C>T p.L216= | Silent (SNP) | VAF 11/33 reads (33%) | called by muse, mutect2, varscan2
- CUZD1 | c.423C>T p.F141= | Silent (SNP) | VAF 24/40 reads (60%) | called by muse, mutect2, varscan2
- CWF19L1 | c.669T>C p.F223= | Silent (SNP) | VAF 39/83 reads (47%) | called by muse, mutect2, varscan2
- FAM205A | c.714G>A p.T238= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as rs776313462; called by mutect2, varscan2
- HS3ST1 | c.210G>A p.L70= | Silent (SNP) | VAF 19/54 reads (35%) | called by muse, mutect2, varscan2
- MAF | c.327C>T p.S109= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as COSV58155134; called by muse, mutect2
- OR8H1 | c.438G>A p.G146= | Silent (SNP) | VAF 11/101 reads (11%) | called by muse, mutect2, varscan2
- PAX6 | c.861C>A p.I287= | Silent (SNP) | VAF 27/73 reads (37%) | called by muse, mutect2, varscan2
- PTPRN | c.2259G>A p.L753= | Silent (SNP) | VAF 19/51 reads (37%) | catalogued as COSV55345259; called by muse, mutect2, varscan2
- REPS1 | c.1830C>G p.L610= (on ENST00000450536 / NM_001286611.2; = p.L609= on NM_031922.4) | Silent (SNP) | VAF 4/68 reads (6%) | called by muse, mutect2
- TIMELESS | c.1383G>A p.V461= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as rs751804119, COSV57512135, COSV57514370; called by muse, mutect2, varscan2
- ZC3H13 | c.1794T>A p.T598= | Silent (SNP) | VAF 28/65 reads (43%) | called by muse, mutect2, varscan2
- ZNF565 | c.618G>A p.L206= (on ENST00000355114; = p.L166= on NM_152477.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 30/80 reads (38%) | called by muse, mutect2, varscan2
- AC109583.1 | c.-542-13712C>G | Intron (SNP) | VAF 9/32 reads (28%) | called by muse, mutect2, varscan2
- AC109583.1 | c.-542-13823C>G | Intron (SNP) | VAF 9/20 reads (45%) | catalogued as COSV101508762; called by muse, mutect2, varscan2
- AIG1 | c.*115G>A | 3'UTR (SNP) | VAF 5/29 reads (17%) | catalogued as rs949000279; called by muse, mutect2
- AP1G2 | c.569-47C>G | Intron (SNP) | VAF 19/58 reads (33%) | called by muse, mutect2, varscan2
- C12orf50 | c.-91C>G | 5'UTR (SNP) | VAF 22/89 reads (25%) | called by muse, mutect2, varscan2
- CSF2RA | c.473+84C>G | Intron (SNP) | VAF 4/10 reads (40%) | called by muse, mutect2
- DDX60L | c.4117-9C>G | Intron (SNP) | VAF 15/39 reads (38%) | called by muse, mutect2, varscan2
- GLRA1 | chr5:151822591 C>A | 3'Flank (SNP) | VAF 7/13 reads (54%) | called by muse, mutect2
- LIAS | c.758-23G>A | Intron (SNP) | VAF 12/22 reads (55%) | called by muse, mutect2, varscan2
- NPHP1 | c.940-56G>C | Intron (SNP) | VAF 5/11 reads (45%) | called by muse, mutect2, varscan2
- PLXNC1 | c.1980+25G>A | Intron (SNP) | VAF 20/50 reads (40%) | catalogued as rs746704315; called by muse, mutect2, varscan2
- RGS14 | c.739+11G>C | Intron (SNP) | VAF 13/32 reads (41%) | catalogued as rs1213633244; called by muse, mutect2, varscan2
- SEL1L2 | c.-6G>A | 5'UTR (SNP) | VAF 8/20 reads (40%) | called by muse, mutect2, varscan2
- SELENOS | c.318+115G>C | Intron (SNP) | VAF 11/29 reads (38%) | called by muse, mutect2, varscan2
- SYNE2 | c.788-696G>C | Intron (SNP) | VAF 10/36 reads (28%) | called by muse, mutect2
- TPP1 | c.508+61G>C | Intron (SNP) | VAF 16/50 reads (32%) | catalogued as rs978291900; called by muse, mutect2
- TTN | c.25532-55C>G | Intron (SNP) | VAF 34/91 reads (37%) | called by muse, mutect2, varscan2
- ZNF181 | c.9+1121G>C | Intron (SNP) | VAF 38/104 reads (37%) | called by muse, mutect2, varscan2
- ZNF570 | chr19:37469351 G>C | 5'Flank (SNP) | VAF 10/19 reads (53%) | called by muse, mutect2, varscan2
